Surgical pathology report (de-identified scan), TCGA case TCGA-VT-AB3D, project TCGA-SARC (Sarcoma), tissue source site Vanderbilt, specimen TCGA-VT-AB3D-01A (Primary Tumor).

[page 1 of 5]
Final Report

100-0-3

Sarcoma, pleomorphic

880513

undifferentiated
8805130 Code to high 880513

Site: Antecubital space
(49.1)

70 5/23/14

DIAGNOSIS:

- 1) SOFT TISSUE, LATERAL MARGIN, LEFT ARM, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 2) SOFT TISSUE, SUPERIOR MARGIN, LEFT ARM, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 3) SOFT TISSUE, INFERIOR MARGIN, LEFT ARM, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 4) SOFT TISSUE, MEDIAL MARGIN, LEFT ARM, BIOPSY: NEGATIVE FOR MALIGNANCY.
- 5) SKIN AND SOFT TISSUE, LEFT ARM, EXCISION: UNDIFFERENTIATED PLEOMORPHIC SARCOMA, FNCLCC GRADE II, 4.2 CM IN GREATEST DIMENSION (SEE SUMMARY FINDINGS).

Soft Tissue Tumors Summary of Findings

Procedure: Wide resection

Tumor Site: Left antecubital fossa, soft tissue.

Tumor Size: 4.2 x 4.0 x 2.5 cm

Macroscopic Extent of Tumor: Deep, subfascial

Histologic Type: Undifferentiated pleomorphic sarcoma (with inflammatory

and focally myxoid stroma)

Mitotic Rate: 13/10 high-power fields (HPF)

(1 HPF x 400 = 0.1734 mm²; X40 objective; most proliferative area)

Necrosis: Not identified

Histologic Grade: FNCLCC Grade II

Margins: negative for sarcoma

[positive at inferior/distal margin on specimen 5 (slide 5J), but additional margins (specimen 3) was negative; On specimen 5, tumor is 0.5

cm, 0.3 cm, 0.2 cm, and 0.1 cm from the proximal, medial, deep, and lateral

margins respectively]

Residual Tumor (R): R0 No residual tumor

Lymph-Vascular Invasion: Not identified

AJCC/UICC Pathologic Staging (pTNM), 7th edition: Stage IIA

Primary Tumor (pT): pT1b, Tumor 5 cm or less in greatest dimension, deep tumor

Regional Lymph Nodes (pN): pNX, Regional lymph nodes cannot be assessed

[page 2 of 5]
Distant Metastasis (pM): Not applicable

Ancillary Studies

Immunohistochemistry: Tumor cells are negative for desmin, smooth muscle

actin, muscle specific actin, S100, Melan-A, AE1/3, and ALK1; Partial immunoreactivity for CD34.

Cytogenetics: Not performed

Molecular Pathology: Not performed

Pre-resection Treatment: No therapy

CLINICAL DATA

Clinical Features: Neoplasm

Operator:

Operation: Left arm (antecubital fossa) mass, wide excision and biopsy

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1)lateral left arm mass margin;
2)superior left arm mass margin;
3)inferior left arm mass margin; 4)medial
left arm mass margin; 5) left arm mass

Instructions to pathologists: Sources 1-4 for frozen section. Source 5-skin

anterior long suture proximal.

GROSS DESCRIPTION:

1) SOURCE: Lateral

Received fresh in a container labeled "", with medical record number and "lateral" is a 0.7 x 0.7 x 0.3 cm portion of red-brown, irregular and beefy soft tissue. No orientation is provided and the specimen is submitted in toto for frozen section analysis.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Superior

Received fresh in a container labeled "", with medical record number and "superior" is a 1.1 x 0.5 x 0.4 cm segment of dark red-brown, irregular and beefy soft tissue. No orientation is provided and the specimen is submitted in toto for frozen section analysis.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Inferior

Received fresh in a container for frozen section analysis labeled with

[page 3 of 5]
the
patient's name " ", medical record number, and "inferior" is
a single, unoriented, irregular red soft tissue fragment consistent
with
skeletal muscle measuring 0.6 x 0.3 x 0.2 cm. The entire specimen is
placed
in a filter bag and submitted in 3AFSC, 1/1.

4) SOURCE: Medial

Received fresh in a container for frozen section analysis labeled with
the
patient's name "", medical record number, and "medial" is a
single, unoriented, irregular red soft tissue fragment consistent with
skeletal muscle measuring 0.9 x 0.6 x 0.3 cm. The entire specimen is
submitted in 4AFSC, 1/1.

5) SOURCE: Left Arm Mass

Received fresh in a container labeled with patient's name "," medical
record number and designated "left arm mass" is an
ellipse of tan-pink skin (4.2 x 1.5 cm) oriented in a superomedial to
inferolateral manner. The skin ellipse overlies a globoid portion of
red-yellow soft tissue (4.5 cm proximal to distal x 4.5 cm medial to
lateral excised to a depth of 3.5 cm) that is oriented with a long
suture
to proximal. The skin surface demonstrates blue-purple ink with no
apparent
masses or lesions. The underlying soft tissue bears a firm, palpable
mass.
The external surface; however, is smooth and glistening with focal
areas of
cautery effect. The specimen is inked as follows: proximal=blue,
distal=green, medial=yellow, lateral=orange, deep=black.

The specimen is serially sectioned revealing a subcutaneous
well-circumscribed nodular lesion abutting all margins. The mass is 0.5
cm
beneath the epidermal surface. There is a dominant nodule measuring 2.5
x
1.8 cm. The dominant nodule is fleshy brown with focal area of
hemorrhage,
possibly consistent with previous biopsy site. The surrounding tissue
varies from red-tan to white and myxoid. The largest dimensions include
4.0
cm medial to lateral x 2.5 cm superficial to deep, and it spans the
entire
distance proximal to distal (approximately 4.2 cm). Representative
sections
are submitted. Gross photographs are taken and a portion of mass is
retained in glutaraldehyde for future possible studies. The remainder
of
the specimen is retained in formalin within its original container.

Summary of sections:

[page 4 of 5]
5A, representative perpendicular section of proximal margin with proximal skin tip, 1/1;
5B-5E, representative full-thickness cross section quartered
5B, superficial medial, 1/1;
5C, deep medial, 1/1;
5D, superficial lateral, 1/1;
5E, deep lateral, 1/1;
5F-5I, representative full-thickness cross section quartered
5F, superficial medial, 1/1;
5G, deep medial, 1/1;
5H, superficial lateral, 1/1;
5I, deep lateral, 1/1
5J, perpendicular section of distal surface and distal skin ellipse, 1/1.

Slides and report reviewed by Attending Pathologist.

SURGICAL PATHOLOGY INTRAOPERATIVE CONSULTATION

1) SOURCE: Lateral

FROZEN SECTION DIAGNOSIS:

1AFS: SOFT TISSUE, LATERAL MARGIN, BIOPSY: NEGATIVE FOR MALIGNANCY.

2) SOURCE: Superior

FROZEN SECTION DIAGNOSIS:

2AFS: SOFT TISSUE, SUPERIOR MARGIN, BIOPSY: NEGATIVE FOR MALIGNANCY.

3) SOURCE: Inferior

FROZEN SECTION DIAGNOSIS:

3AFS: SOFT TISSUE, INFERIOR MARGIN, BIOPSY: NEGATIVE FOR MALIGNANCY.

4) SOURCE: Medial

FROZEN SECTION DIAGNOSIS:

4AFS: SOFT TISSUE, MEDIAL MARGIN, BIOPSY: NEGATIVE FOR MALIGNANCY.

Electronically signed by: _____, Attending Pathologist

—
The following special studies were performed on this case and the interpretation is incorporated in the diagnostic report above:

[page 5 of 5]
1xDESMIN, 1xS-100 STAIN, 1xMELANA, 1xAE1 AE3 (COCKTAIL), 1xCD34,
1xACTIN
MUS SMOOTH, 1xACTIN MUS SPECIFIC, 1xALK1

In some tests, analyte specific reagents (ASRs) are used. In the case of

an ASR, this test was developed and its performance characteristics determined by this laboratory. It has not been cleared or approved by the

US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

Source: NCI Genomic Data Commons file 89302607-9e05-4403-bee7-f8f1759c4bf8 (TCGA-VT-AB3D.CCD15521-CBDA-443F-AFA1-867269C61AE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).